Somatic mutation profile of tumor specimen TCGA-EK-A3GM-01A (aliquot TCGA-EK-A3GM-01A-11D-A20U-09) from TCGA case TCGA-EK-A3GM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 65.4 years (23,879 days).
Specimen TCGA-EK-A3GM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52663de1-9414-4cbf-bdc7-efd459731414.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A3GM-10A (Blood Derived Normal), aliquot TCGA-EK-A3GM-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fbfd1b6-b192-4497-bc14-98ac5ec427e3

The open-access MAF lists 183 somatic variants for this specimen: 132 protein-altering or splice-affecting, 51 silent.
By variant classification: Missense Mutation 116, Silent 51, Nonsense Mutation 10, Splice Region 2, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.657T>A p.F219L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV57247054, COSV57254375; called by muse, mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 38/168 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.4186C>T p.L1396F (on ENST00000372530 / NM_001198934.2; = p.L1368F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs761216822, COSV55088409; called by muse, mutect2, varscan2
- ACTC1 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.969); catalogued as COSV51759333; called by muse, mutect2, varscan2
- ADGRA2 | c.2511G>A p.A837= | Splice Region (SNP) | VAF 13/40 reads (33%) | catalogued as rs143283233; called by muse, mutect2, varscan2
- ADGRF2 | c.1172G>A p.R391K (on ENST00000296862 / NM_001368115.2; = p.R323K on NM_153839.7) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.038); catalogued as COSV57288560; called by muse, mutect2, varscan2
- ADGRG2 | c.373G>A p.E125K (on ENST00000379869 / NM_001079858.3; = p.E122K on NM_005756.4) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.348); catalogued as COSV61339277, COSV61340221; called by muse, mutect2, varscan2
- ADGRG4 | c.8305C>G p.H2769D | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV54952482, COSV54957109; called by muse, mutect2, varscan2
- AGO2 | c.2306G>A p.W769* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV55047889; called by muse, mutect2, varscan2
- ARHGAP35 | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1278020073, COSV68331616, COSV68331861; called by mutect2, varscan2
- ARNT2 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV57585669; called by muse, mutect2
- ATAD3A | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59233631; called by muse, mutect2, varscan2
- ATP10B | c.801G>C p.E267D | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); catalogued as rs760110312, COSV58779000; called by muse, mutect2, varscan2
- ATXN2L | c.1376C>A p.S459* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100294332, COSV57371067; called by muse, mutect2, varscan2
- AWAT1 | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV65738554; called by muse, mutect2, varscan2
- BAK1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1051911; called by muse, mutect2, varscan2
- BARD1 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.036); catalogued as COSV53612389; called by muse, mutect2, varscan2
- BOD1L1 | c.8587C>T p.Q2863* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as COSV50014702; called by muse, mutect2, varscan2
- BRCA1 | c.5044G>A p.E1682K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs80356958, COSV58790756; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- BRINP3 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66511641, COSV66523421; called by muse, mutect2, varscan2
- BSN | c.7415G>A p.R2472Q | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as rs781034873, COSV56519014; called by muse, mutect2, varscan2
- CACNA1E | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs769941881, COSV62394979, COSV62397581; called by muse, mutect2, varscan2
- CACNA2D1 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.543); catalogued as rs1386978066, COSV62380453; called by muse, mutect2, varscan2
- CCDC160 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV66251654; called by muse, mutect2, varscan2
- CCDC88C | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs200829106, COSV101105979; called by muse, mutect2, varscan2
- CDH23 | c.6879C>G p.F2293L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56466395; called by muse, mutect2, varscan2
- CENPB | c.1242_1256del p.E415_E419del | In Frame Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs754367212; called by mutect2, varscan2
- CFH | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs138890387, CM134084, COSV66408057; called by muse, mutect2
- CHD6 | c.6215G>A p.R2072Q | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs181643165; called by muse, mutect2, varscan2
- COL21A1 | c.859C>G p.Q287E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV55164457; called by muse, mutect2, varscan2
- CSTF2T | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as rs760010167, COSV58656568; called by muse, mutect2, varscan2
- CTNNA3 | c.602G>A p.R201K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.973); catalogued as rs372957321, COSV101050707; called by muse, mutect2, varscan2
- CYP3A43 | c.733G>C p.V245L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV55936254; called by muse, mutect2, varscan2
- DNAH1 | c.9583G>A p.G3195R | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs868500538, COSV70229394; called by muse, mutect2, varscan2
- DOP1B | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.229); catalogued as rs146155717; called by muse, mutect2, varscan2
- DSP | c.6052A>G p.I2018V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.558); catalogued as COSV65793060; called by muse, mutect2, varscan2
- DYNC1H1 | c.8986G>A p.E2996K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV64137381; called by muse, mutect2, varscan2
- EPHA3 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60703304; called by muse, mutect2, varscan2
- ERBB2 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV54068645, COSV99508444; called by muse, mutect2, varscan2
- ERCC4 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.341); catalogued as COSV61312195; called by muse, mutect2
- ESPL1 | c.1978C>G p.L660V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57759771; called by muse, mutect2, varscan2
- EXPH5 | c.5245C>G p.Q1749E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as COSV56202791; called by muse, mutect2, varscan2
- EYS | c.811A>G p.S271G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV60986652; called by muse, mutect2, varscan2
- FBN3 | c.5239G>A p.E1747K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs199650269; called by muse, mutect2, varscan2
- GPR153 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs768218848, COSV64938588; called by muse, mutect2
- GPS1 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | catalogued as COSV57649225; called by muse, mutect2, varscan2
- GSTCD | c.553G>A p.E185K (on ENST00000360505 / NM_001031720.3; = p.E98K on NM_024751.3) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.794); catalogued as COSV64733557; called by muse, mutect2
- GTF3C1 | c.75G>C p.W25C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55181472; called by muse, mutect2, varscan2
- HAUS2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV53000181; called by muse, mutect2, varscan2
- HPN | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs753366151, COSV52883858; called by muse, mutect2, varscan2
- HSPA4L | c.1013T>C p.I338T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs139697778; called by muse, mutect2, varscan2
- IAPP | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs200996235, COSV53714074; called by muse, mutect2, varscan2
- IFIH1 | c.2530G>C p.E844Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55127005, COSV99718408; called by muse, mutect2
- KDM2A | c.1065G>C p.Q355H | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV67082192; called by muse, mutect2, varscan2
- KDM2A | c.1155G>C p.L385F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV67082195; called by muse, mutect2, varscan2
- KIF23 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV52980112; called by muse, mutect2, varscan2
- KLF15 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56179556; called by muse, mutect2, varscan2
- KLHL10 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs782816075, COSV53173316; called by muse, mutect2, varscan2
- KMT2C | c.4999G>T p.E1667* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV51444130, COSV51478783, COSV51524677; called by muse, mutect2
- LIPG | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.21); catalogued as rs750648857, COSV54294741; called by muse, mutect2, varscan2
- LRP1B | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV67224998; called by muse, mutect2, varscan2
- MAGED2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.593); catalogued as rs779634966, COSV54497890; called by muse, mutect2, varscan2
- MAMDC4 | c.1845G>A p.R615= | Splice Region (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100440421; called by muse, mutect2, varscan2
- MNS1 | c.1127G>C p.R376T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV53068493, COSV99549515; called by muse, mutect2, varscan2
- MUC20 | c.1580G>A p.R527K | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV57850584; called by muse, mutect2, varscan2
- MUC4 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.55); catalogued as COSV62152606; called by muse, mutect2, varscan2
- MYO3B | c.2432-1G>A p.X811_splice | Splice Site (SNP) | VAF 8/49 reads (16%) | catalogued as COSV58698184, COSV58701319; called by muse, mutect2
- MYO7A | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs781959420, COSV68684084; called by muse, mutect2, varscan2
- NAA80 | c.148G>A p.E50K (on ENST00000417393 / NM_001200018.2; = p.E72K on NM_012191.4) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV56497744, COSV99807474; called by muse, mutect2, varscan2
- NARS2 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55251968; called by muse, mutect2, varscan2
- NCAM1 | c.1814C>T p.T605M (on ENST00000316851 / NM_181351.5; = p.T595M on NM_000615.7) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782353037, COSV57517108; called by muse, mutect2, varscan2
- NLRP8 | c.2940C>A p.N980K | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1242628157, COSV52588124; called by muse, mutect2, varscan2
- NRXN3 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV73585398; called by muse, mutect2, varscan2
- NUTM2F | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53557813; called by mutect2, varscan2
- OLFML1 | c.1097G>A p.R366K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.579); catalogued as COSV55077491, COSV55082012; called by muse, mutect2, varscan2
- PCDHGA5 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.135); catalogued as COSV53920326, COSV53955956; called by muse, mutect2, varscan2
- PHF20 | c.1850C>G p.S617C | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs780974892, COSV59186309; called by muse, mutect2, varscan2
- PLXNA3 | c.5115G>T p.Q1705H | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV63754206; called by muse, mutect2, varscan2
- PLXNB1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as rs1384681298, COSV56490177, COSV56495380; called by muse, mutect2
- POU4F2 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs757268615, COSV55584588, COSV55586816; called by muse, mutect2, varscan2
- PPP1R14A | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.76); catalogued as COSV56646503; called by muse, mutect2, varscan2
- PRDM16 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as rs369539275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRPF6 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs1369865859, COSV53871263; called by muse, varscan2
- PRUNE2 | c.6485C>G p.S2162C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100944606, COSV65041948; called by muse, mutect2, varscan2
- PTCD1 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1387200235, COSV52857707; called by muse, mutect2, varscan2
- PTPRD | c.5611G>C p.D1871H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61933475, COSV61958476; called by muse, mutect2, varscan2
- RANBP9 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); catalogued as COSV50581752; called by muse, mutect2
- RIF1 | c.5030G>C p.R1677T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); catalogued as COSV54617598; called by muse, mutect2, varscan2
- RMI1 | c.1322A>G p.K441R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV57936434; called by muse, mutect2
- ROBO3 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186571971, COSV67300811; called by muse, mutect2, varscan2
- RPL4 | c.567G>C p.M189I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.017); catalogued as COSV57180495; called by muse, mutect2, varscan2
- RPS4X | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.289); catalogued as COSV60181678; called by muse, mutect2, varscan2
- RUNX2 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61839899; called by muse, mutect2, varscan2
- RUNX3 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs759577669, COSV100137002; called by muse, mutect2, varscan2
- RYR3 | c.9757G>A p.E3253K (on ENST00000389232; = p.E3254K on NM_001036.6) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.31); catalogued as rs774163504, COSV66791228; called by muse, mutect2, varscan2
- SAXO2 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV59754138; called by muse, mutect2, varscan2
- SESN2 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV53427715; called by muse, mutect2, varscan2
- SLC38A11 | c.493A>G p.I165V (on ENST00000409149 / NM_001351539.1; = p.I143V on NM_173512.2) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs368927720; called by muse, mutect2, varscan2
- SLFNL1 | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.348); catalogued as COSV57234700; called by muse, mutect2, varscan2
- SMARCA5 | c.2944C>T p.Q982* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV51644599; called by muse, mutect2, varscan2
- SOX5 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.028); catalogued as COSV58630918; called by muse, mutect2, varscan2
- SPTBN1 | c.4147G>A p.E1383K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.435); catalogued as COSV61689001; called by muse, mutect2
- SSRP1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV53479586; called by muse, mutect2, varscan2
- STS | c.402G>C p.M134I | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV54268575; called by muse, mutect2, varscan2
- SWAP70 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV59664133; called by muse, mutect2, varscan2
- SYNE2 | c.19753G>A p.D6585N | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.574); catalogued as COSV59952251, COSV59963699; called by muse, mutect2, varscan2
- SYNPO | c.1651T>C p.S551P (on ENST00000394243 / NM_001166208.2; = p.S307P on NM_007286.6) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV56940487; called by muse, varscan2
- TDRD10 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs1438526406, COSV52725259; called by muse, mutect2, varscan2
- TECPR2 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1230843715, COSV63970832; called by muse, mutect2, varscan2
- TET1 | c.2939C>T p.S980L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV65385041; called by muse, mutect2, varscan2
- THSD1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.178); catalogued as rs763256441, COSV51628772, COSV99319032; called by muse, mutect2, varscan2
- TMEM223 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763596886, COSV53668680; called by muse, mutect2, varscan2
- TNRC6A | c.3362C>G p.S1121C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV59364604; called by muse, mutect2, varscan2
- TOGARAM2 | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65421715, COSV65423931; called by muse, varscan2
- TP53BP2 | c.1339G>A p.D447N (on ENST00000343537 / NM_001031685.3; = p.D318N on NM_005426.2) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.051); catalogued as COSV59068883; called by muse, mutect2, varscan2
- TRIM52 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs1458245185, COSV59844336; called by muse, mutect2, varscan2
- TRIOBP | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as rs966116669, COSV60378050; called by muse, mutect2, varscan2
- TRMT44 | c.1768C>G p.H590D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV67664017; called by muse, mutect2, varscan2
- TTC3 | c.1903G>C p.E635Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV61290709; called by muse, mutect2, varscan2
- TTN | c.73318G>A p.E24440K (on ENST00000591111; = p.E17016K on NM_003319.4) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | PolyPhen probably damaging (0.994); catalogued as COSV60089070; called by muse, mutect2, varscan2
- WDR90 | c.3524C>G p.S1175C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53470426; called by muse, mutect2, varscan2
- XXYLT1 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV59984330; called by muse, mutect2
- YTHDC2 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV50741437; called by muse, mutect2, varscan2
- ZBTB21 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV60404216; called by muse, mutect2, varscan2
- ZDHHC13 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67980731, COSV67981033; called by mutect2, varscan2
- ZIK1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs199973825, COSV56737003; called by muse, mutect2, varscan2
- ZNF667 | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV52634915; called by muse, mutect2, varscan2
- ZNF780A | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.722); catalogued as COSV100575099, COSV61815531; called by muse, mutect2, varscan2
- ARID1A | c.1690_1694dup p.Q566Nfs*55 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- ARID1B | c.5666del p.K1889Sfs*72 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- ZNF26 | c.767A>T p.K256I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ACKR3 | c.210C>T p.I70= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV56022003; called by muse, mutect2, varscan2
- APOF | c.228C>T p.F76= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV58475740; called by muse, mutect2, varscan2
- ARHGEF2 | c.780C>T p.L260= (on ENST00000361247 / NM_001162383.2; = p.L232= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV58111475; called by muse, mutect2, varscan2
- ATP2B4 | c.594C>T p.L198= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV58178401; called by muse, mutect2, varscan2
- BCL2L1 | c.246C>G p.P82= | Silent (SNP) | VAF 41/264 reads (16%) | catalogued as COSV56967710; called by muse, mutect2, varscan2
- BCO2 | c.573C>T p.L191= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs755205861, COSV63063532; called by muse, mutect2, varscan2
- BSG | c.210C>G p.L70= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100344439, COSV61077111; called by muse, mutect2, varscan2
- CACNG5 | c.384G>A p.T128= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs777938474, COSV50056200; called by muse, mutect2, varscan2
- CACNG6 | c.603G>A p.Q201= (on ENST00000252729 / NM_145814.1; = p.Q130= on NM_031897.2) | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV53166868; called by muse, mutect2, varscan2
- CCDC57 | c.2568C>T p.L856= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs763124452, COSV100148116; called by muse, mutect2, varscan2
- CDKN1A | c.153C>T p.F51= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs200541845, COSV99781343; called by muse, mutect2, varscan2
- CEP72 | c.753G>A p.Q251= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as COSV53793047; called by muse, mutect2, varscan2
- EPB41L4A | c.852C>T p.L284= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV54870486; called by muse, varscan2
- FBH1 | c.2274C>T p.A758= (on ENST00000362091 / NM_178150.3; = p.A809= on NM_032807.4) | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs141613808; called by muse, mutect2, varscan2
- FSCN1 | c.1185C>T p.I395= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs763345590, COSV61017684; called by muse, mutect2, varscan2
- GALNT17 | c.1782G>A p.K594= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV61160549; called by muse, mutect2, varscan2
- GALNT7 | c.339C>T p.L113= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV53930291; called by muse, mutect2, varscan2
- GJC2 | c.66C>T p.F22= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV64512672; called by muse, mutect2, varscan2
- GLB1L3 | c.372G>A p.P124= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs199664947, COSV66281805; called by muse, mutect2, varscan2
- GPR153 | c.756C>A p.I252= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV64938583; called by muse, mutect2, varscan2
- GRIN2C | c.2283C>T p.I761= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs546891526, COSV53111451; called by muse, mutect2
- GUCY1B1 | c.1350C>G p.L450= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV52375938; called by muse, mutect2, varscan2
- KIR2DL1 | c.741G>A p.L247= | Silent (SNP) | VAF 65/391 reads (17%) | catalogued as COSV52410177; called by muse, mutect2, varscan2
- KLHL6 | c.1758G>A p.L586= | Silent (SNP) | VAF 40/199 reads (20%) | catalogued as COSV58066677; called by muse, mutect2, varscan2
- LCP2 | c.18G>A p.V6= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV50451409; called by muse, mutect2, varscan2
- MCOLN3 | c.126C>G p.L42= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV62014353; called by muse, varscan2
- MCOLN3 | c.60C>T p.C20= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV62014370; called by muse, varscan2
- NBEAL2 | c.6516C>T p.R2172= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs970326287, COSV99436914; called by muse, mutect2, varscan2
- NHLRC3 | c.288C>T p.F96= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs939885659, COSV61487592; called by muse, mutect2, varscan2
- OSBPL2 | c.600C>T p.I200= (on ENST00000313733 / NM_144498.4; = p.I188= on NM_014835.4) | Silent (SNP) | VAF 54/146 reads (37%) | catalogued as COSV58216881; called by muse, mutect2, varscan2
- PCDHB5 | c.1866G>A p.E622= | Silent (SNP) | VAF 51/223 reads (23%) | catalogued as rs782126921, COSV50652777; called by muse, mutect2, varscan2
- PISD | c.1140C>T p.I380= (on ENST00000439502 / NM_001326412.1; = p.I346= on NM_014338.3) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs769378162, COSV99837339; called by muse, mutect2, varscan2
- PLXNC1 | c.702C>T p.F234= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs772793582, COSV51575978, COSV51578026; called by muse, mutect2, varscan2
- PRAMEF15 | c.384C>G p.L128= | Silent (SNP) | VAF 48/156 reads (31%) | called by muse, mutect2, varscan2
- PTPN12 | c.534C>T p.L178= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99950572; called by muse, mutect2, varscan2
- RBP3 | c.2337G>A p.V779= | Silent (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- SLC26A8 | c.1387C>T p.L463= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV62887195; called by muse, mutect2, varscan2
- SPIN3 | c.12G>A p.P4= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs753148068, COSV66529222; called by muse, mutect2, varscan2
- STAT5B | c.2316C>T p.L772= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs758060015, COSV53182853; called by muse, mutect2, varscan2
- SYT1 | c.720C>T p.I240= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs1378146593, COSV54048701; called by muse, mutect2, varscan2
- TAF2 | c.2484C>A p.L828= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100978771, COSV65421300; called by muse, mutect2, varscan2
- TIAM1 | c.396C>T p.S132= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV54552828, COSV54566105; called by muse, mutect2, varscan2
- TMEM59L | c.321C>T p.C107= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1421732559, COSV53242345; called by muse, mutect2, varscan2
- TTC6 | c.396C>T p.I132= (on ENST00000267368; = p.I1498= on NM_001310135.3) | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV57449313; called by mutect2, varscan2
- TTLL3 | c.696C>T p.F232= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs773317292, COSV59614050; called by muse, mutect2, varscan2
- UBAP2L | c.2262C>T p.S754= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs1482295245, COSV99671869; called by muse, mutect2, varscan2
- ZC3H12C | c.960C>T p.F320= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV53709152; called by muse, mutect2, varscan2
- ZFHX4 | c.1683C>T p.D561= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs757915266, COSV50731706; called by muse, mutect2, varscan2
- ZNF318 | c.6114C>G p.V2038= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV58932930; called by muse, mutect2, varscan2
- ZNF35 | c.1065C>T p.I355= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV56076631; called by muse, mutect2, varscan2
- ZNF417 | c.1605C>G p.L535= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV100364352; called by muse, mutect2
